Somatic mutation profile of tumor specimen TCGA-UN-AAZ9-01A (aliquot TCGA-UN-AAZ9-01A-11D-A382-10) from TCGA case TCGA-UN-AAZ9, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 76.3 years (27,851 days).
Specimen TCGA-UN-AAZ9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ba6a468c-601f-49b0-965e-3b81785be2f4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-UN-AAZ9-10A (Blood Derived Normal), aliquot TCGA-UN-AAZ9-10A-01D-A385-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/404f601a-b4d6-4ab9-89ea-cae8ff35e861

The open-access MAF lists 25 somatic variants for this specimen: 23 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 15, Nonsense Mutation 4, Silent 2, Frame Shift Del 1, In Frame Del 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHCTF1 | c.323T>G p.V108G (on ENST00000366508; = p.V82G on NM_015446.5) | Missense Mutation (SNP) | VAF 36/383 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.408); catalogued as COSV100404322; called by muse, mutect2, varscan2
- BICDL2 | c.937G>A p.D313N | Missense Mutation (SNP) | VAF 39/82 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV54158457; called by muse, mutect2, varscan2
- CDC14A | c.218C>T p.S73L | Missense Mutation (SNP) | VAF 43/57 reads (75%) | SIFT deleterious (0.01); PolyPhen benign (0.093); catalogued as COSV100325840; called by muse, mutect2, varscan2
- CHFR | c.1489G>C p.A497P (on ENST00000432561 / NM_001161345.1; = p.A456P on NM_018223.2) | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV99905670; called by muse, mutect2, varscan2
- DOCK11 | c.6089T>G p.I2030S | Missense Mutation (SNP) | VAF 326/425 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52239067, COSV99354570; called by muse, mutect2, varscan2
- EPB41L4A | c.339T>A p.Y113* | Nonsense Mutation (SNP) | VAF 177/644 reads (27%) | catalogued as COSV99813986; called by muse, mutect2, varscan2
- FBXL19 | c.1476G>T p.W492C | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as COSV100609314; called by muse, mutect2, varscan2
- FTCD | c.1064G>C p.G355A | Missense Mutation (SNP) | VAF 217/476 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99385400; called by muse, mutect2, varscan2
- GPR158 | c.46C>T p.Q16* | Nonsense Mutation (SNP) | VAF 38/96 reads (40%) | catalogued as COSV100894207, COSV66275892; called by muse, mutect2, varscan2
- MAP3K19 | c.581C>A p.S194* | Nonsense Mutation (SNP) | VAF 66/179 reads (37%) | catalogued as COSV100209121, COSV59640235; called by muse, mutect2, varscan2
- MYO18A | c.1688A>T p.D563V | Missense Mutation (SNP) | VAF 82/211 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV100572622; called by muse, mutect2, varscan2
- PER1 | c.3505C>T p.Q1169* | Nonsense Mutation (SNP) | VAF 35/80 reads (44%) | catalogued as COSV100424809; called by muse, mutect2, varscan2
- RFX6 | c.858+1G>A p.X286_splice | Splice Site (SNP) | VAF 43/56 reads (77%) | catalogued as rs758981961, COSV100264195; called by muse, mutect2, varscan2
- SERPINF1 | c.512G>A p.G171D | Missense Mutation (SNP) | VAF 52/112 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99628944; called by muse, mutect2
- SLC7A14 | c.28C>A p.P10T | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV99200864; called by muse, mutect2, varscan2
- SNRPA1 | c.392A>G p.Y131C | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99574685; called by muse, mutect2, varscan2
- SUSD6 | c.431C>G p.P144R | Missense Mutation (SNP) | VAF 43/50 reads (86%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100713504; called by muse, mutect2, varscan2
- TRIM36 | c.1910C>G p.T637S | Missense Mutation (SNP) | VAF 67/187 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV99142604; called by muse, mutect2, varscan2
- ZNF418 | c.333G>T p.R111S | Missense Mutation (SNP) | VAF 157/399 reads (39%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.916); catalogued as COSV101268879, COSV101268988; called by muse, mutect2, varscan2
- CENPF | c.6652del p.Q2218Kfs*12 | Frame Shift Del (DEL) | VAF 204/323 reads (63%) | called by mutect2, pindel, varscan2
- FOXC1 | c.1236dup p.Q413Afs*115 | Frame Shift Ins (INS) | VAF 40/69 reads (58%) | called by pindel, varscan2
- PXDNL | c.910C>A p.Q304K | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.173); called by muse, mutect2
- TTN | c.35679_35684del p.K11894_K11895del (on ENST00000591111; = p.K4470_K4471del on NM_003319.4) | In Frame Del (DEL) | VAF 66/143 reads (46%) | called by mutect2, pindel, varscan2
- ARHGEF25 | c.294T>A p.G98= | Silent (SNP) | VAF 40/90 reads (44%) | catalogued as COSV99678251; called by muse, mutect2, varscan2
- HS3ST3A1 | c.1041G>A p.K347= | Silent (SNP) | VAF 129/414 reads (31%) | catalogued as COSV99404488; called by muse, mutect2, varscan2
